Somatic mutation profile of tumor specimen MP2PRT-PATKFS-TMP1-A (aliquot MP2PRT-PATKFS-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATKFS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,331 days).
Specimen MP2PRT-PATKFS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc9e1391-43ba-46fd-a0ae-0eca24b49c52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKFS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKFS-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01993049-742d-41c3-beef-95637edd76d7

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 10, Intron 1, In Frame Ins 1, Nonsense Mutation 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASP12 | c.930A>C p.Q310H | Missense Mutation (SNP) | VAF 143/273 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100998320; called by muse, mutect2, varscan2
- FANCF | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 26/878 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59415665; called by muse, mutect2
- FBXW7 | c.1392_1393insTCA p.V464_R465insS (on ENST00000281708 / NM_001349798.2; = p.V384_R385insS on NM_018315.5) | In Frame Ins (INS) | VAF 50/448 reads (11%) | catalogued as COSV55909503; called by mutect2, pindel, varscan2
- HMCN1 | c.4414G>A p.A1472T | Missense Mutation (SNP) | VAF 93/351 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs763411017, COSV54949176; called by muse, mutect2, varscan2
- IQANK1 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 300/533 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs912770530; called by muse, mutect2, varscan2
- SAMD9L | c.2539G>T p.E847* | Nonsense Mutation (SNP) | VAF 15/486 reads (3%) | catalogued as COSV59081513; called by muse, mutect2
- ZNF235 | c.984C>G p.F328L | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV52155112, COSV52156919; called by muse, mutect2
- ADAMTS7 | c.1874A>G p.D625G | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- GART | c.2426G>C p.R809T | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); called by muse, mutect2
- GRIN2B | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 184/472 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MPP4 | c.1304C>A p.P435H | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPICE1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- TBC1D24 | c.1334T>A p.V445E (on ENST00000646147 / NM_001199107.2; = p.V439E on NM_020705.3) | Missense Mutation (SNP) | VAF 74/805 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TEX13B | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- VAV1 | c.1315G>C p.D439H | Missense Mutation (SNP) | VAF 27/452 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); called by muse, mutect2
- ZNF678 | c.428A>C p.H143P (on ENST00000343776 / NM_001367910.1; = p.H198P on NM_178549.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASB14 | c.1107C>G p.L369= | Silent (SNP) | VAF 12/363 reads (3%) | called by muse, mutect2
- C20orf202 | c.177G>A p.L59= | Silent (SNP) | VAF 24/436 reads (6%) | called by muse, mutect2
- GPR88 | c.504C>T p.L168= | Silent (SNP) | VAF 30/914 reads (3%) | catalogued as rs1267677398; called by muse, mutect2
- MFSD13A | c.228G>T p.R76= | Silent (SNP) | VAF 151/366 reads (41%) | called by muse, mutect2, varscan2
- MNT | c.1132C>T p.L378= | Silent (SNP) | VAF 30/1062 reads (3%) | catalogued as rs1335250182; called by muse, mutect2
- PCDHA3 | c.1683C>T p.N561= | Silent (SNP) | VAF 480/1061 reads (45%) | catalogued as COSV63543435; called by muse, mutect2, varscan2
- PTPN2 | c.642C>T p.I214= | Silent (SNP) | VAF 30/652 reads (5%) | catalogued as COSV58998888; called by muse, mutect2
- SLC2A4 | c.1050G>A p.R350= | Silent (SNP) | VAF 21/730 reads (3%) | called by muse, mutect2
- SPN | c.1071G>A p.A357= | Silent (SNP) | VAF 32/844 reads (4%) | catalogued as rs914647648; called by muse, mutect2
- SRGAP1 | c.861G>A p.A287= | Silent (SNP) | VAF 236/558 reads (42%) | catalogued as rs137909926; called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins TCTCT | 5'Flank (INS) | VAF 20/61 reads (33%) | called by pindel, varscan2
- IGHV4-61 | chr14:106639118 ins TCTCT | 3'Flank (INS) | VAF 31/180 reads (17%) | called by pindel, varscan2
- SCD5 | c.569+19670G>C | Intron (SNP) | VAF 15/473 reads (3%) | called by muse, mutect2
